Somatic mutation profile of tumor specimen MMRF_2402_1_BM_CD138pos (aliquot MMRF_2402_1_BM_CD138pos_T1_KHS5U_K15223) from MMRF case MMRF_2402, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 70.9 years (25,884 days).
Specimen MMRF_2402_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a2ef89fb-5c23-4beb-bcba-ce38dbed7eba.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2402_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2402_1_PB_Whole_C2_KHS5U_K15212; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8ccd3b5a-c1e9-4c22-8c29-64680ca5f682

The open-access MAF lists 116 somatic variants for this specimen: 48 protein-altering or splice-affecting, 14 silent, 54 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 42, 3'UTR 30, Silent 14, Intron 14, 5'UTR 4, 3'Flank 4, Frame Shift Del 3, 5'Flank 2, Splice Region 1, Translation Start Site 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.64C>A p.Q22K | Missense Mutation (SNP) | VAF 71/162 reads (44%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs121913236, CM070964, COSV55526911, COSV55779357; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- C9orf43 | c.523G>A p.A175T | Missense Mutation (SNP) | VAF 56/188 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs142991325, COSV55912773; called by muse, mutect2, varscan2
- CALN1 | c.248G>A p.R83H (on ENST00000329008 / NM_001017440.3; = p.R125H on NM_031468.4) | Missense Mutation (SNP) | VAF 33/49 reads (67%) | SIFT tolerated (0.17); PolyPhen benign (0.081); catalogued as rs771972574, COSV100210142, COSV61119556; called by muse, mutect2, varscan2
- CRTAM | c.596G>A p.R199Q | Missense Mutation (SNP) | VAF 99/357 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.116); catalogued as rs1265633376, COSV57067299; called by muse, mutect2, varscan2
- CSF1 | c.1300G>A p.V434M | Missense Mutation (SNP) | VAF 63/121 reads (52%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.8); catalogued as rs146089530; called by muse, mutect2, varscan2
- DENND2B | c.2371del p.R791Gfs*22 | Frame Shift Del (DEL) | VAF 50/188 reads (27%) | catalogued as COSV58203062, COSV58208576; called by mutect2, pindel, varscan2
- DRD3 | c.445C>T p.R149C | Missense Mutation (SNP) | VAF 46/118 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs200010990, COSV55682241, COSV55683723; called by muse, mutect2, varscan2
- DSCAM | c.5183C>T p.T1728M | Missense Mutation (SNP) | VAF 178/459 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.959); catalogued as rs767893246, COSV68031013; called by muse, mutect2, varscan2
- IGHV2-70 | c.281C>G p.T94S | Missense Mutation (SNP) | VAF 52/56 reads (93%) | SIFT deleterious (0.01); PolyPhen benign (0.306); catalogued as rs372813642; called by muse, varscan2
- IGHV2-70 | c.95A>G p.K32R | Missense Mutation (SNP) | VAF 31/31 reads (100%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); catalogued as rs371469802; called by muse, varscan2
- IGHV2-70 | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 18/18 reads (100%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.876); catalogued as rs534553794; called by muse, mutect2, varscan2
- IGHV3-33 | c.308A>G p.N103S | Missense Mutation (SNP) | VAF 77/81 reads (95%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.02); catalogued as rs544955791; called by muse, mutect2, varscan2
- IGLV3-1 | c.308A>C p.D103A | Missense Mutation (SNP) | VAF 96/190 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs376677833; called by muse, varscan2
- IGLV3-1 | c.327G>A p.W109* | Nonsense Mutation (SNP) | VAF 83/181 reads (46%) | catalogued as rs759893584; called by muse, varscan2
- IGSF11 | c.1114_1115del p.L372Gfs*22 (on ENST00000393775 / NM_001015887.3; = p.L371Gfs*22 on NM_152538.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 146/295 reads (49%) | catalogued as rs1332241623; called by pindel, varscan2
- JPH1 | c.1087G>A p.A363T | Missense Mutation (SNP) | VAF 56/150 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1415301244, COSV60608530; called by muse, mutect2, varscan2
- MYO3A | c.3100G>A p.G1034R | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1401845047, COSV99779534; called by muse, mutect2, varscan2
- PCDHGA12 | c.2588G>A p.S863N | Missense Mutation (SNP) | VAF 51/111 reads (46%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.285); catalogued as rs1180757756; called by muse, mutect2, varscan2
- PLEC | c.11909C>T p.T3970M (on ENST00000322810 / NM_201380.4; = p.T3860M on NM_000445.5) | Missense Mutation (SNP) | VAF 42/75 reads (56%) | SIFT tolerated (0.17); PolyPhen benign (0.403); catalogued as rs189389994; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLEKHF1 | c.479G>A p.R160H | Missense Mutation (SNP) | VAF 89/403 reads (22%) | SIFT tolerated (0.66); PolyPhen benign (0.108); catalogued as rs1480033368; called by muse, mutect2, varscan2
- PTCH2 | c.545C>T p.P182L | Missense Mutation (SNP) | VAF 108/207 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773912063; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PTGS1 | c.1651G>A p.G551S | Missense Mutation (SNP) | VAF 40/145 reads (28%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); catalogued as rs775470716; called by muse, mutect2, varscan2
- SALL3 | c.3607C>T p.R1203W | Missense Mutation (SNP) | VAF 86/188 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs761052930; called by muse, mutect2, varscan2
- SLA | c.352+7G>A | Splice Region (SNP) | VAF 31/83 reads (37%) | catalogued as rs113718860; called by muse, mutect2, varscan2
- SP140 | c.203G>A p.R68Q | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1326194173, COSV59449921; called by muse, mutect2, varscan2
- SPDEF | c.281C>T p.P94L | Missense Mutation (SNP) | VAF 65/127 reads (51%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.926); catalogued as rs372475042; called by muse, mutect2, varscan2
- SPTBN4 | c.1583G>A p.R528Q | Missense Mutation (SNP) | VAF 58/225 reads (26%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.878); catalogued as rs145007629; called by muse, varscan2
- ZNF804B | c.550A>G p.T184A | Missense Mutation (SNP) | VAF 104/239 reads (44%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV60815345; called by muse, mutect2, varscan2
- ANKRD31 | c.857C>T p.P286L | Missense Mutation (SNP) | VAF 101/212 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- BRCA1 | c.4205A>T p.H1402L | Missense Mutation (SNP) | VAF 73/157 reads (46%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCDC42 | c.625G>A p.E209K | Missense Mutation (SNP) | VAF 77/179 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- COL6A6 | c.1931T>G p.F644C | Missense Mutation (SNP) | VAF 135/217 reads (62%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- CRBN | c.1286C>T p.T429I | Missense Mutation (SNP) | VAF 41/147 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- DAAM2 | c.2376C>A p.S792R | Missense Mutation (SNP) | VAF 31/48 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- DLGAP3 | c.280C>G p.P94A | Missense Mutation (SNP) | VAF 44/118 reads (37%) | SIFT tolerated (0.47); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- EP300 | c.7078del p.E2360Nfs*43 | Frame Shift Del (DEL) | VAF 103/250 reads (41%) | called by mutect2, pindel, varscan2
- HJURP | c.1679A>T p.K560I | Missense Mutation (SNP) | VAF 80/144 reads (56%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.726); called by muse, mutect2
- HMX3 | c.800C>G p.T267S | Missense Mutation (SNP) | VAF 37/81 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- HSH2D | c.1022A>T p.Y341F | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- IGSF9B | c.3148C>A p.L1050M | Missense Mutation (SNP) | VAF 13/185 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.796); called by muse, mutect2
- LIPC | c.1262A>G p.E421G | Missense Mutation (SNP) | VAF 43/147 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- LRP1B | c.11270A>C p.Y3757S | Missense Mutation (SNP) | VAF 32/69 reads (46%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2, varscan2
- NFASC | c.65G>A p.G22D | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT tolerated (0.23); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- PRKD1 | c.783G>T p.K261N | Missense Mutation (SNP) | VAF 74/164 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.248); called by muse, mutect2, varscan2
- RABGAP1 | c.2930A>T p.N977I | Missense Mutation (SNP) | VAF 68/233 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- YTHDC2 | c.811A>G p.T271A | Missense Mutation (SNP) | VAF 47/95 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.267); called by muse, mutect2, varscan2
- ZNF585A | c.1058C>A p.S353Y (on ENST00000292841 / NM_001288800.2; = p.S298Y on NM_152655.3) | Missense Mutation (SNP) | VAF 316/644 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ZNF816 | c.1562G>A p.R521K | Missense Mutation (SNP) | VAF 67/228 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- IGHV3-33 | c.78T>G p.S26= | Silent (SNP) | VAF 64/70 reads (91%) | catalogued as rs1417684124; called by muse, varscan2
- IQGAP1 | c.1494C>T p.L498= | Silent (SNP) | VAF 47/185 reads (25%) | catalogued as rs776379118; called by muse, mutect2, varscan2
- KIR3DL3 | c.933G>T p.L311= | Silent (SNP) | VAF 77/432 reads (18%) | called by muse, mutect2, varscan2
- KIRREL3 | c.720G>A p.T240= | Silent (SNP) | VAF 16/57 reads (28%) | catalogued as rs754939539, COSV73105296; called by muse, mutect2, varscan2
- LRP1B | c.3901T>C p.L1301= | Silent (SNP) | VAF 36/65 reads (55%) | called by muse, mutect2, varscan2
- MOGAT3 | c.231G>A p.S77= | Silent (SNP) | VAF 67/131 reads (51%) | catalogued as rs772742733; called by muse, varscan2
- NISCH | c.3978G>A p.G1326= | Silent (SNP) | VAF 79/263 reads (30%) | catalogued as rs762107696; called by muse, mutect2, varscan2
- PDE3B | c.3255T>C p.D1085= | Silent (SNP) | VAF 189/325 reads (58%) | called by muse, mutect2, varscan2
- PLXND1 | c.3924G>A p.L1308= | Silent (SNP) | VAF 73/279 reads (26%) | called by muse, mutect2, varscan2
- PRDM9 | c.939C>A p.A313= | Silent (SNP) | VAF 32/117 reads (27%) | catalogued as COSV57004468; called by muse, mutect2, varscan2
- SEC14L1 | c.1716A>G p.Q572= | Silent (SNP) | VAF 42/121 reads (35%) | catalogued as rs767548190; called by muse, mutect2, varscan2
- SVEP1 | c.6978G>A p.P2326= | Silent (SNP) | VAF 51/178 reads (29%) | catalogued as rs543043187, COSV99929060; called by muse, mutect2, varscan2
- ZNF141 | c.420C>T p.T140= | Silent (SNP) | VAF 37/80 reads (46%) | called by muse, mutect2, varscan2
- ZNF470 | c.1923A>G p.R641= | Silent (SNP) | VAF 31/138 reads (22%) | called by muse, mutect2, varscan2
- ASPG | c.192-87G>A | Intron (SNP) | VAF 35/80 reads (44%) | called by muse, mutect2, varscan2
- BNIP2 | c.*4252A>G | 3'UTR (SNP) | VAF 20/66 reads (30%) | called by muse, mutect2
- BNIPL | c.*1008C>T | 3'UTR (SNP) | VAF 62/116 reads (53%) | called by muse, mutect2, varscan2
- CSPP1 | c.2237-40A>C | Intron (SNP) | VAF 15/29 reads (52%) | called by muse, mutect2, varscan2
- CYLC2 | c.*592del | 3'UTR (DEL) | VAF 24/88 reads (27%) | catalogued as rs970103132; called by mutect2, varscan2
- DIP2A | c.*2224A>T | 3'UTR (SNP) | VAF 21/34 reads (62%) | called by muse, mutect2, varscan2
- FHL2 | chr2:105399257 C>T | 5'Flank (SNP) | VAF 104/206 reads (50%) | catalogued as rs969938524; called by muse, mutect2, varscan2
- FOXN3 | chr14:89158605 G>A | 3'Flank (SNP) | VAF 3/25 reads (12%) | called by muse, mutect2
- GRB7 | c.586-45A>G | Intron (SNP) | VAF 77/159 reads (48%) | called by muse, mutect2, varscan2
- GRIP2 | c.*86C>A | 3'UTR (SNP) | VAF 6/18 reads (33%) | called by muse, mutect2
- GUCY1A2 | c.1207-16120G>T | Intron (SNP) | VAF 20/40 reads (50%) | called by muse, mutect2, varscan2
- H4C9 | c.*54A>C | 3'UTR (SNP) | VAF 56/129 reads (43%) | called by muse, mutect2, varscan2
- HOXD8 | c.-347G>A | 5'UTR (SNP) | VAF 17/30 reads (57%) | called by muse, mutect2, varscan2
- IER2 | c.-38C>T | 5'UTR (SNP) | VAF 50/222 reads (23%) | catalogued as rs1401843156; called by muse, mutect2, varscan2
- JDP2 | chr14:75471253 G>T | 3'Flank (SNP) | VAF 52/109 reads (48%) | called by muse, mutect2, varscan2
- KCNAB1 | c.276-129704A>G | Intron (SNP) | VAF 17/74 reads (23%) | called by muse, mutect2, varscan2
- KCTD16 | c.*3220A>T | 3'UTR (SNP) | VAF 20/45 reads (44%) | called by muse, mutect2, varscan2
- KLK9 | c.*55G>A | 3'UTR (SNP) | VAF 4/14 reads (29%) | called by muse, mutect2
- MECP2 | c.*7811G>C | 3'UTR (SNP) | VAF 54/56 reads (96%) | called by muse, mutect2, varscan2
- MMAA | chr4:145659336 T>C | 3'Flank (SNP) | VAF 19/47 reads (40%) | called by muse, mutect2, varscan2
- MYO15B | c.8053+44A>T | Intron (SNP) | VAF 24/42 reads (57%) | called by muse, mutect2, varscan2
- NDUFA9 | c.*1866A>T | 3'UTR (SNP) | VAF 18/45 reads (40%) | catalogued as rs942209312; called by muse, mutect2, varscan2
- NECAB1 | c.*1980C>T | 3'UTR (SNP) | VAF 9/34 reads (26%) | catalogued as rs984181200; called by muse, mutect2, varscan2
- NF2 | c.1737+1952G>T | Intron (SNP) | VAF 47/101 reads (47%) | catalogued as rs1432438163; called by muse, mutect2, varscan2
- NFIB | c.*6313T>G | 3'UTR (SNP) | VAF 40/73 reads (55%) | called by muse, mutect2, varscan2
- NGLY1 | c.*196A>G | 3'UTR (SNP) | VAF 59/96 reads (61%) | catalogued as rs1383225767; called by muse, mutect2, varscan2
- NHSL1 | c.676+4934del | Intron (DEL) | VAF 19/50 reads (38%) | called by mutect2, pindel, varscan2
- NRCAM | c.1207+57C>T | Intron (SNP) | VAF 38/70 reads (54%) | catalogued as rs1052672069, COSV61031979; called by muse, mutect2, varscan2
- NUP58 | c.1435+2030T>C | Intron (SNP) | VAF 24/51 reads (47%) | called by muse, mutect2, varscan2
- NXNL2 | c.-155G>T | 5'UTR (SNP) | VAF 95/286 reads (33%) | called by muse, mutect2, varscan2
- OR4Q2 | chr14:20003224 C>T | 3'Flank (SNP) | VAF 3/12 reads (25%) | catalogued as rs977732520; called by muse, mutect2
- PAX7 | c.*3544C>T | 3'UTR (SNP) | VAF 51/124 reads (41%) | catalogued as rs780952871; called by muse, mutect2, varscan2
- PEAK1 | c.*1298A>G | 3'UTR (SNP) | VAF 29/86 reads (34%) | catalogued as rs559810523; called by muse, mutect2, varscan2
- RAB21 | c.*1864A>T | 3'UTR (SNP) | VAF 21/43 reads (49%) | called by muse, mutect2, varscan2
- RABEP1 | c.528+1332C>T | Intron (SNP) | VAF 14/25 reads (56%) | catalogued as rs1237666306; called by muse, mutect2, varscan2
- RETSAT | c.*1006G>A | 3'UTR (SNP) | VAF 62/182 reads (34%) | called by muse, mutect2
- RHOJ | c.*7C>G | 3'UTR (SNP) | VAF 102/209 reads (49%) | called by muse, mutect2, varscan2
- S1PR2 | c.-43+790G>C | Intron (SNP) | VAF 79/139 reads (57%) | catalogued as rs567584132; called by muse, mutect2, varscan2
- SDC2 | c.*1887del | 3'UTR (DEL) | VAF 26/80 reads (33%) | catalogued as rs906211812; called by mutect2, pindel, varscan2
- SEMA5A | c.*2707C>A | 3'UTR (SNP) | VAF 14/50 reads (28%) | catalogued as rs1423220216; called by muse, mutect2, varscan2
- SLC9A3R2 | chr16:2025437 G>A | 5'Flank (SNP) | VAF 5/12 reads (42%) | catalogued as rs529232900; called by muse, mutect2, varscan2
- TBC1D9B | c.1417-129G>A | Intron (SNP) | VAF 12/22 reads (55%) | called by muse, mutect2, varscan2
- TDRD9 | c.1582-56C>T | Intron (SNP) | VAF 21/53 reads (40%) | catalogued as rs886857129; called by muse, mutect2, varscan2
- TMEM192 | c.*2894C>T | 3'UTR (SNP) | VAF 24/45 reads (53%) | called by muse, mutect2, varscan2
- TRAF3 | c.*1823A>G | 3'UTR (SNP) | VAF 23/63 reads (37%) | called by muse, mutect2, varscan2
- TRIO | c.*1497G>A | 3'UTR (SNP) | VAF 21/79 reads (27%) | called by muse, mutect2, varscan2
- TUB | c.*3323T>C | 3'UTR (SNP) | VAF 42/65 reads (65%) | called by muse, mutect2, varscan2
- UBFD1 | c.*3728del | 3'UTR (DEL) | VAF 8/89 reads (9%) | catalogued as rs1205932595, COSV54843421; called by pindel, varscan2*
- UBXN7 | c.*3499T>C | 3'UTR (SNP) | VAF 63/89 reads (71%) | called by muse, mutect2, varscan2
- VSTM2A | c.*341C>T | 3'UTR (SNP) | VAF 32/82 reads (39%) | called by muse, mutect2, varscan2
- ZEB2 | c.-7C>G | 5'UTR (SNP) | VAF 85/202 reads (42%) | called by muse, mutect2, varscan2
- ZNF385D | c.*150G>T | 3'UTR (SNP) | VAF 4/22 reads (18%) | called by muse, mutect2
- ZNF681 | c.*3420C>T | 3'UTR (SNP) | VAF 50/108 reads (46%) | called by muse, mutect2, varscan2
- ZNF681 | c.*1615T>C | 3'UTR (SNP) | VAF 38/78 reads (49%) | called by muse, mutect2, varscan2
